Somatic mutation profile of tumor specimen TCGA-A6-6781-01B (aliquot TCGA-A6-6781-01B-06D-A270-10) from TCGA case TCGA-A6-6781, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 43.4 years (15,842 days).
Specimen TCGA-A6-6781-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0646e1f-d5ac-4fcd-ad1b-ebc9d8964848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6781-10A (Blood Derived Normal), aliquot TCGA-A6-6781-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59aff61b-76a6-45b9-bbe0-f148179cf7ea

The open-access MAF lists 1,314 somatic variants for this specimen: 938 protein-altering or splice-affecting, 282 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 659, Silent 282, Frame Shift Del 186, Nonsense Mutation 46, 3'UTR 36, Intron 28, Frame Shift Ins 22, RNA 11, Splice Site 10, Splice Region 9, 3'Flank 8, 5'Flank 6.

Variants (750 of 1,314; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSG2 | c.2533del p.I845* | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | catalogued as rs1375081885; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- GBE1 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369574719; ClinVar: pathogenic / uncertain significance; called by mutect2, varscan2
- GLDC | c.1888C>T p.R630* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as rs751025203, COSV58675982; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as rs386833517, CM061029, COSV58675961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAT2 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 3/17 reads (18%) | catalogued as rs1403825722, COSV63555168; ClinVar: pathogenic; called by muse, varscan2
- MLH1 | c.588del p.K196Nfs*6 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | catalogued as rs63751653, CM151408, COSV51624461; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs1555614947, CM143375, COSV62191417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC16A1 | c.41del p.P14Qfs*10 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs121913321; ClinVar: pathogenic; called by pindel, varscan2
- USH2A | c.11156G>A p.R3719H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs527236139, CM148283, COSV56321550; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.8890del p.W2964Gfs*10 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs786205116; ClinVar: pathogenic; called by mutect2, pindel
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | catalogued as rs751284215; called by mutect2, varscan2
- ABCA13 | c.2842A>G p.I948V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs779473888, COSV70025475; called by muse, mutect2, varscan2
- ABCC4 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978321113; called by muse, mutect2, varscan2
- ABHD18 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as rs773100732, COSV66292887; called by muse, mutect2, varscan2
- ABL2 | c.3481G>A p.G1161R (on ENST00000502732 / NM_007314.4; = p.G1146R on NM_005158.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1467885528, COSV61010680; called by muse, mutect2, varscan2
- AC090517.4 | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV50995640; called by muse, mutect2, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACKR3 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1325541874, COSV56020269; called by muse, mutect2
- ACOT2 | c.26A>G p.H9R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99468736; called by muse, mutect2, varscan2
- ACP5 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs745604493, COSV54535093; called by muse, mutect2, varscan2
- ACP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753445095, COSV58698145; called by muse, mutect2, varscan2
- ACSBG1 | c.1447del p.H483Tfs*23 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV51909719; called by pindel, varscan2
- ACTL6A | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.68); catalogued as rs773240025, COSV66998577; called by muse, mutect2, varscan2
- ACTR5 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.051); catalogued as rs748333992; called by muse, mutect2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as rs1250515265, COSV61700920; called by muse, mutect2, varscan2
- ADAM10 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as rs752797397, COSV53048879; called by muse, mutect2, varscan2
- ADAM22 | c.1733C>T p.T578M | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55968532; called by muse, mutect2, varscan2
- ADAMTS7 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV66305615; called by muse, varscan2
- ADAMTS8 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1031384898, COSV57290808; called by muse, mutect2
- ADCY5 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1459977492; called by muse, mutect2
- ADCY5 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59193338; called by muse, mutect2, varscan2
- ADD1 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs913024832, COSV53265909; called by muse, mutect2, varscan2
- ADGB | c.4409C>T p.A1470V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs747324258, COSV58846630; called by mutect2, varscan2
- ADGRB1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60091183; called by muse, mutect2, varscan2
- AFF4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs780771766, COSV54793422; called by muse, mutect2, varscan2
- ALG13 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767153325, COSV52634625, COSV99322475; called by muse, mutect2, varscan2
- ALKBH1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537248458; called by muse, mutect2, varscan2
- ALPK3 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV51928387, COSV51940020; called by muse, mutect2
- ALS2 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs747774956, COSV51889758; called by muse, mutect2, varscan2
- AMOT | c.3074C>A p.A1025D (on ENST00000371959 / NM_001113490.1; = p.A616D on NM_133265.3) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as COSV59059812; called by muse, mutect2, varscan2
- AMOTL1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.098); catalogued as rs371806495, COSV54414848; called by muse, mutect2, varscan2
- ANKDD1A | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs572642318; called by muse, mutect2, varscan2
- ANKMY2 | c.907G>A p.V303I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs768714189, COSV100186992; called by muse, mutect2, varscan2
- ANKS1A | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64458497; called by muse, mutect2, varscan2
- ANO5 | c.898dup p.I300Nfs*36 | Frame Shift Ins (INS) | VAF 7/56 reads (13%) | catalogued as rs1383346134; called by mutect2, pindel, varscan2
- ANO9 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV60447955; called by muse, mutect2, varscan2
- ANXA1 | c.801C>T p.I267= | Splice Region (SNP) | VAF 9/55 reads (16%) | catalogued as rs757586479, COSV57410254; called by muse, mutect2, varscan2
- ANXA6 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905412; called by muse, varscan2
- AP2B1 | c.1558C>T p.R520* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV51996586; called by muse, mutect2, varscan2
- APC | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.246); catalogued as rs372416031, COSV57346229; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLF | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs150464758; called by muse, mutect2, varscan2
- APOB | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51939474; called by muse, mutect2, varscan2
- APOBEC1 | c.207del p.K69Nfs*12 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | catalogued as rs753365818; called by mutect2, pindel, varscan2
- AQP10 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV61474316; called by muse, mutect2, varscan2
- ARHGAP35 | c.4096A>G p.K1366E | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV68328891; called by muse, mutect2, varscan2
- ARHGEF10L | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as COSV63414767; called by muse, mutect2, varscan2
- ARHGEF10L | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1292671192, COSV51426980; called by muse, mutect2, varscan2
- ARHGEF2 | c.1667G>A p.R556Q (on ENST00000361247 / NM_001162383.2; = p.R528Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV100560709, COSV58105714; called by muse, mutect2, varscan2
- ARHGEF40 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs753025691, COSV53877914; called by mutect2, varscan2
- ARID5B | c.3310C>T p.Q1104* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV54414378, COSV99689389; called by muse, mutect2, varscan2
- ARMC4 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.892); catalogued as rs776293552, COSV59454922, COSV59461869; called by muse, mutect2, varscan2
- ARSG | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV101477882, COSV101477889; called by muse, mutect2, varscan2
- ASPM | c.1780A>G p.T594A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54123575; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 16/132 reads (12%) | catalogued as rs866490133; called by mutect2, varscan2
- ATAD2B | c.920del p.K307Rfs*57 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs1558707706; called by mutect2, pindel, varscan2
- ATIC | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV52691504; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP2B1 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs570457928, COSV53803084, COSV99666296; called by muse, mutect2, varscan2
- ATP2B4 | c.2263C>T p.R755* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as rs756353643, COSV58180406; called by muse, mutect2, varscan2
- ATP5F1C | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 55/269 reads (20%) | catalogued as rs1436478284, COSV59620786; called by muse, mutect2, varscan2
- ATP6V1H | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.069); catalogued as rs770965453, COSV100778731, COSV62216636; called by mutect2, varscan2
- ATP8A1 | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52527326; called by muse, mutect2, varscan2
- ATP9A | c.1291del p.Q431Sfs*22 | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | catalogued as COSV58766683; called by mutect2, pindel, varscan2
- AXDND1 | c.2227C>T p.R743* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as rs771074994, COSV62647551, COSV62648978; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs778012871; called by pindel, varscan2
- AXL | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs138219571; called by mutect2, varscan2
- BACH2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1460936502, COSV57599410; called by muse, varscan2
- BARHL1 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.705); catalogued as rs1368618643; called by muse, mutect2, varscan2
- BCL2L11 | c.574C>T p.R192C (on ENST00000393256 / NM_138621.5; = p.R132C on NM_006538.5) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758817904, COSV58027602; called by muse, varscan2
- BLZF1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs369684533, COSV100250614; called by muse, mutect2, varscan2
- BMF | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV55018504; called by muse, mutect2, varscan2
- BMS1 | c.2115T>A p.D705E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV65732748; called by muse, mutect2, varscan2
- BRIP1 | c.2054A>C p.Q685P | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51993186; called by muse, mutect2, varscan2
- BRSK2 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57539457; called by muse, mutect2, varscan2
- BRWD3 | c.3061T>C p.S1021P | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV64743359; called by muse, mutect2, varscan2
- C11orf24 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs543093269, COSV100422528; called by muse, mutect2, varscan2
- C14orf93 | c.1497_1499del p.E501del | In Frame Del (DEL) | VAF 11/56 reads (20%) | catalogued as rs1431730242; called by pindel, varscan2
- C15orf39 | c.1038del p.S347Lfs*30 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs774177293; called by mutect2, pindel, varscan2
- C4BPA | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.734); catalogued as rs762693425, COSV65535547; called by muse, mutect2, varscan2
- C7orf31 | c.358del p.S120Vfs*9 | Frame Shift Del (DEL) | VAF 36/261 reads (14%) | catalogued as rs750735753; called by mutect2, pindel, varscan2
- C8B | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs760472969, COSV100980740; called by muse, mutect2, varscan2
- CABIN1 | c.5017C>T p.R1673C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.226); catalogued as rs749933147, COSV54076896; called by muse, mutect2, varscan2
- CACHD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); catalogued as rs1329242081, COSV51547183; called by muse, mutect2, varscan2
- CACNA1B | c.4352G>A p.R1451Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1289601418, COSV53111739, COSV99499705; called by muse, mutect2, varscan2
- CACNA1E | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760975849, COSV62380904; called by muse, mutect2, varscan2
- CACNB1 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.987); catalogued as rs866053848, COSV59999711; called by muse, mutect2, varscan2
- CADPS | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs182039177, COSV51865292; called by muse, mutect2, varscan2
- CAPN14 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs764024066, COSV67289649; called by muse, mutect2, varscan2
- CARMIL1 | c.4011G>T p.Q1337H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV100277382; called by muse, mutect2, varscan2
- CASR | c.1802G>A p.R601H (on ENST00000490131; = p.R678H on NM_000388.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs1278025825, CM165796, COSV56139931, COSV56142619; ClinVar: uncertain significance; called by muse, mutect2
- CASZ1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775345608, COSV59738714; called by muse, mutect2, varscan2
- CCDC106 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.197); catalogued as rs200120422; called by mutect2, varscan2
- CCDC113 | c.767T>C p.V256A | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV99540827; called by muse, mutect2, varscan2
- CCDC136 | c.3143del p.K1048Sfs*3 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs761237807; called by mutect2, varscan2
- CCDC159 | c.441G>T p.E147D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52258348; called by muse, mutect2
- CCDC178 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.303); catalogued as COSV55756734; called by muse, mutect2
- CCDC24 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763595255, COSV58842286; called by muse, mutect2, varscan2
- CCDC28B | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs201902661, COSV99356411, COSV99356456; called by mutect2, varscan2
- CCDC62 | c.1775C>T p.T592M | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.584); catalogued as rs142626019; called by mutect2, varscan2
- CCDC66 | c.1510C>T p.R504C (on ENST00000394672 / NM_001353147.1; = p.R470C on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs765969408, COSV58300851; called by muse, mutect2, varscan2
- CCDC8 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs754734333, COSV56772049; called by muse, mutect2, varscan2
- CCDC88B | c.3854G>A p.R1285H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756702849, COSV57264692; called by muse, mutect2, varscan2
- CCNL1 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs948726021, COSV55818059; called by muse, mutect2, varscan2
- CD101 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756924215, COSV56715644, COSV56715779; called by muse, mutect2, varscan2
- CD19 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV61187649; called by muse, mutect2, varscan2
- CD247 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs760895755, COSV62976678; called by muse, mutect2, varscan2
- CD79B | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148032848, COSV50077193, COSV50079859; called by muse, mutect2
- CDC42EP3 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54875053; called by muse, mutect2, varscan2
- CDCA4 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs1312795304, COSV60314883; called by muse, mutect2, varscan2
- CDH11 | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs767812673, COSV51750088; called by muse, mutect2, varscan2
- CDHR5 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs764791491, COSV57641059; called by muse, mutect2, varscan2
- CDK14 | c.1249G>A p.E417K (on ENST00000380050 / NM_001287135.2; = p.E399K on NM_012395.3) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.06); catalogued as rs368151673; called by muse, mutect2, varscan2
- CDK3 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764108595, COSV56909699; called by muse, mutect2, varscan2
- CDON | c.2344G>A p.V782I | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs1182235163, COSV54994616; called by muse, mutect2, varscan2
- CDX4 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV100999152, COSV65171389; called by muse, mutect2, varscan2
- CDYL | c.1625C>T p.S542L (on ENST00000328908 / NM_001368125.1; = p.S488L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs370584550; called by muse, mutect2, varscan2
- CELF1 | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs746684771, COSV60110836; called by muse, mutect2, varscan2
- CEP126 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1266921377; called by muse, mutect2
- CEP164 | c.2984A>C p.Q995P | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV99632899; called by muse, mutect2, varscan2
- CEP192 | c.5989C>T p.R1997C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs746335630, COSV58059353; called by muse, mutect2, varscan2
- CEP89 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537113854, COSV99993297; called by mutect2, varscan2
- CFAP45 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141306445; called by muse, mutect2, varscan2
- CFAP45 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV63647844; called by muse, mutect2, varscan2
- CFAP65 | c.4855C>T p.R1619* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as rs765282879, COSV100444982, COSV58557378; called by mutect2, varscan2
- CFAP69 | c.2061del p.K687Nfs*43 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs1275710203; called by pindel, varscan2
- CFHR4 | c.857G>A p.R286H (on ENST00000367416 / NM_001201551.2; = p.R287H on NM_001201550.3) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.362); catalogued as rs188298928, COSV52223632, COSV99054624; called by muse, mutect2, varscan2
- CGB8 | c.438del p.S147Afs*? | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as COSV56822738; called by mutect2, pindel, varscan2
- CHAF1A | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs753582271, COSV56669738; called by muse, varscan2
- CHAF1B | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58439050; called by muse, mutect2, varscan2
- CHD3 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 5/70 reads (7%) | catalogued as COSV57872079; called by muse, mutect2
- CHFR | c.718G>A p.A240T (on ENST00000432561 / NM_001161345.1; = p.A199T on NM_018223.2) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs533118486, COSV99905155; called by muse, mutect2, varscan2
- CHI3L2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs778552657, COSV63873224; called by muse, mutect2, varscan2
- CHMP6 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs762854982, COSV57327932; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA10 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763121060, COSV51703869; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs762321510; called by pindel, varscan2
- CLCA4 | c.208dup p.R70Kfs*13 | Frame Shift Ins (INS) | VAF 27/173 reads (16%) | catalogued as rs148031684; called by mutect2, pindel, varscan2
- CLCN2 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1325778309, COSV55599415; called by muse, mutect2, varscan2
- CLCN6 | c.213+1G>T p.X71_splice | Splice Site (SNP) | VAF 12/76 reads (16%) | catalogued as COSV56737615; called by muse, mutect2, varscan2
- CLIC6 | c.1910C>T p.T637M (on ENST00000360731 / NM_001317009.2; = p.T619M on NM_053277.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141470374; called by muse, mutect2, varscan2
- CMC4 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782008762, COSV62898338; called by muse, mutect2, varscan2
- CNTLN | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV52064098; called by muse, mutect2, varscan2
- CNTLN | c.3601G>A p.V1201I | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs568907262, COSV52064115; called by muse, mutect2, varscan2
- COBL | c.3282del p.K1094Nfs*20 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs1562810271; called by mutect2, pindel, varscan2
- COG4 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV60420987; called by muse, mutect2, varscan2
- COL13A1 | c.1195A>G p.K399E (on ENST00000398978 / NM_001130103.2; = p.K342E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100637386; called by muse, mutect2, varscan2
- COL1A1 | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99866817; called by muse, mutect2, varscan2
- COL5A2 | c.2879G>C p.G960A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66406601; called by muse, mutect2, varscan2
- COL5A3 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs556243775, COSV53405293; called by muse, mutect2, varscan2
- COL6A3 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV99797182; called by muse, mutect2, varscan2
- CORIN | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.804); catalogued as COSV56684912, COSV56689184; called by muse, varscan2
- CPA6 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.68); PolyPhen benign (0.406); catalogued as rs1018666393, COSV52719710, COSV52732409; called by muse, mutect2
- CPSF6 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1331705563, COSV57011848; called by muse, mutect2, varscan2
- CPT1B | c.2122G>A p.A708T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs757184617, COSV56414818; called by muse, mutect2, varscan2
- CRIM1 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.667); catalogued as rs1173656893, COSV54858684; called by muse, mutect2, varscan2
- CRLF3 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs774317573, COSV60835116; called by muse, mutect2, varscan2
- CRYM | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs148349291, CM112951; called by muse, mutect2, varscan2
- CSMD1 | c.8506G>T p.G2836* (on ENST00000520002; = p.G2835* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV59276382; called by muse, varscan2
- CSMD3 | c.9253G>T p.G3085C (on ENST00000297405 / NM_001363185.1; = p.G2916C on NM_052900.3) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52090391; called by muse, mutect2, varscan2
- CTNND1 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV62381970; called by muse, mutect2, varscan2
- CTSF | c.511A>G p.N171D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59747207; called by muse, mutect2, varscan2
- CXADR | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as COSV53027575; called by muse, mutect2, varscan2
- CXCL8 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.424); catalogued as COSV100266221; called by muse, mutect2, varscan2
- CYP2B6 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs138594605; called by mutect2, varscan2
- CYP3A4 | c.140del p.L47Wfs*43 | Frame Shift Del (DEL) | VAF 9/90 reads (10%) | catalogued as rs1036437989; called by mutect2, pindel, varscan2
- CYP4A22 | c.1364+7C>T | Splice Region (SNP) | VAF 7/42 reads (17%) | catalogued as rs755535332, COSV53737743; called by muse, mutect2, varscan2
- CYP4F3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV55406706; called by muse, mutect2
- DAB1 | c.1385G>A p.R462H (on ENST00000371231; = p.R429H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs144347021, COSV64692596; called by mutect2, varscan2
- DAZAP1 | c.770del p.P257Rfs*78 | Frame Shift Del (DEL) | VAF 5/21 reads (24%) | catalogued as COSV99245498; called by mutect2, pindel, varscan2
- DCP1A | c.1148A>G p.N383S | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV99587903; called by muse, mutect2, varscan2
- DDHD2 | c.1973G>A p.R658H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763476356, COSV68157058; called by mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs1176416201; called by mutect2, varscan2
- DDX21 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs200756197, COSV62555017; called by muse, mutect2, varscan2
- DDX39B | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV66018368; called by muse, mutect2, varscan2
- DDX6 | c.369G>A p.Q123= | Splice Region (SNP) | VAF 22/131 reads (17%) | catalogued as COSV50587530; called by muse, mutect2, varscan2
- DEFA5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs137962701; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | catalogued as COSV59384233; called by pindel, varscan2
- DGKH | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs150403121; called by muse, mutect2, varscan2
- DHX16 | c.2819G>A p.R940H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773747627, COSV53312321; called by mutect2, varscan2
- DIDO1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56612657; called by muse, mutect2
- DIP2B | c.4207G>A p.G1403S | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs758467662; called by muse, mutect2, varscan2
- DMKN | c.1100A>C p.K367T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100303381; called by muse, mutect2, varscan2
- DNAH1 | c.10682C>T p.P3561L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553642627, COSV70225849; called by muse, mutect2, varscan2
- DNAH1 | c.11051C>A p.A3684D | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV101325259; called by muse, mutect2
- DNAH10 | c.12905G>A p.R4302H (on ENST00000409039; = p.R4241H on NM_207437.3) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs775827104, COSV53018383; called by muse, mutect2, varscan2
- DNAH5 | c.5927del p.G1976Efs*78 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as rs1233412023, COSV54222791; called by mutect2, pindel, varscan2
- DNAH6 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.021); catalogued as rs1263374947, COSV99405823; called by muse, mutect2, varscan2
- DNAH6 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599477, COSV52888451; called by muse, mutect2, varscan2
- DNAH8 | c.7628G>A p.R2543Q | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs543347999, COSV100544145; called by muse, mutect2, varscan2
- DNAJB6 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs771003490, COSV51094092; called by mutect2, varscan2
- DNHD1 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775587577, COSV54429409; called by muse, mutect2, varscan2
- DOCK11 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); catalogued as rs1174860954, COSV52232844; called by muse, mutect2, varscan2
- DOCK11 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV52232853; called by muse, varscan2
- DOCK3 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs752734538, COSV99813264; called by muse, mutect2, varscan2
- DOK4 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757770307, COSV54671571; called by muse, mutect2, varscan2
- DOK5 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773975138, COSV52815822; called by muse, mutect2
- DPCD | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs757346528, COSV64509367; called by muse, mutect2, varscan2
- DSCAM | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as COSV68019901; called by muse, mutect2
- DSP | c.7702G>A p.G2568S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs139486943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTX4 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs376061897; called by muse, mutect2, varscan2
- DUOX1 | c.3484G>A p.V1162I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as rs151144648; called by mutect2, varscan2
- DYNC1H1 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV64133914; called by muse, mutect2, varscan2
- ECHDC2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764403275, COSV64299953; called by muse, mutect2, varscan2
- ECT2 | c.2605A>G p.S869G (on ENST00000392692 / NM_001349098.2; = p.S838G on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV51686046; called by muse, mutect2
- EEF2K | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs143471765; called by muse, mutect2, varscan2
- EFCAB8 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1432050228, COSV68699564; called by muse, varscan2
- EHD1 | c.741del p.E248Rfs*50 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs774171970, COSV57737231; called by mutect2, pindel, varscan2
- EID2B | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs753248992, COSV58318679; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as rs762590530, COSV57514257; called by mutect2, varscan2
- ELMO1 | c.2030T>C p.M677T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60293724; called by muse, mutect2
- ELOA | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69309269; called by muse, mutect2, varscan2
- EML6 | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234073690; called by muse, mutect2, varscan2
- ENAM | c.1372T>C p.W458R | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV101253002; called by muse, mutect2, varscan2
- ENAM | c.3263C>T p.T1088M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs139404568; called by muse, mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs759157900, COSV56136050; called by mutect2, varscan2
- ENKD1 | c.202_210del p.E68_G70del | In Frame Del (DEL) | VAF 7/27 reads (26%) | catalogued as COSV54675092; called by mutect2, pindel, varscan2
- EPC2 | c.1140G>T p.Q380H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); catalogued as COSV51539418; called by muse, mutect2, varscan2
- EPHA5 | c.2049A>G p.A683= | Splice Region (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56627934; called by muse, mutect2, varscan2
- ERCC6L | c.2234C>A p.P745H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as COSV57819722; called by muse, mutect2, varscan2
- ETV1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54140084; called by muse, mutect2, varscan2
- ETV3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63864291; called by muse, mutect2, varscan2
- EVI5 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752893341, COSV100789673, COSV63278771; called by muse, mutect2, varscan2
- EXPH5 | c.5303G>C p.S1768T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1188277966, COSV56198382, COSV99762411; called by muse, mutect2
- EZH2 | c.1823G>A p.R608Q (on ENST00000460911 / NM_001203247.2; = p.R613Q on NM_004456.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs561605379, COSV100236491; called by muse, mutect2, varscan2
- F2R | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV59929093; called by muse, varscan2
- FAM166A | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100458124; called by muse, mutect2, varscan2
- FAM169A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs778097956, COSV65845836; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 18/102 reads (18%) | catalogued as rs768952789; called by mutect2, varscan2
- FAM20A | c.755_757del p.F252del | In Frame Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs768121766; called by pindel, varscan2
- FAM20B | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55379147; called by muse, mutect2, varscan2
- FAM214A | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV55921640; called by muse, mutect2, varscan2
- FAM98A | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV53208719; called by muse, mutect2, varscan2
- FANCD2OS | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs759648564, COSV55047390; called by muse, mutect2, varscan2
- FANCI | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV55521999; called by muse, mutect2, varscan2
- FAT1 | c.6743C>T p.P2248L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367776554; called by muse, mutect2, varscan2
- FAT3 | c.10615G>A p.V3539M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs531488417, COSV53070681, COSV53169706; called by muse, mutect2, varscan2
- FBN1 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752450678, COSV57307989; called by muse, mutect2, varscan2
- FCGR2B | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV52680463; called by muse, mutect2, varscan2
- FER1L5 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as rs772718482, COSV70068285; called by muse, mutect2, varscan2
- FER1L5 | c.2980C>T p.R994C (on ENST00000623019; = p.R1001C on NM_001293083.2) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1037047259; called by muse, varscan2
- FER1L6 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs200724975, COSV67547680; called by muse, mutect2, varscan2
- FGA | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1276352833, CM082670, COSV57392315; called by muse, mutect2, varscan2
- FGD5 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs762771281, COSV53236481; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | catalogued as rs777980924; called by pindel, varscan2
- FLNC | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs766755439, COSV100367735, COSV57954261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMO4 | c.817A>G p.I273V | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV63000528; called by muse, mutect2, varscan2
- FMO5 | c.407del p.K136Rfs*3 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV99567435; called by mutect2, pindel, varscan2
- FNDC1 | c.5351G>A p.R1784Q | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs747207185, COSV51929669; called by muse, mutect2, varscan2
- FOXRED2 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs764123276, COSV53398740, COSV99068177; called by muse, mutect2
- FREM2 | c.4558C>T p.R1520W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142322683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRYL | c.1714A>G p.M572V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV51937858; called by muse, mutect2, varscan2
- FUS | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs1269972112; called by muse, mutect2, varscan2
- FUT2 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.238); catalogued as COSV67178864; called by muse, mutect2, varscan2
- FUT8 | c.1322G>A p.R441Q (on ENST00000360689 / NM_001371534.1; = p.R278Q on NM_004480.4) | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758856033, COSV61290251; called by mutect2, varscan2
- GABRA5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.826); catalogued as COSV100164945, COSV59482802; called by muse, mutect2
- GAD1 | c.755del p.X252_splice | Splice Site (DEL) | VAF 4/16 reads (25%) | catalogued as COSV60152140; called by mutect2, pindel, varscan2
- GALNT8 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs200878740, COSV52894184, COSV99362470; called by muse, mutect2
- GARNL3 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs756264516, COSV59223438; called by muse, mutect2, varscan2
- GCN1 | c.7328G>A p.R2443H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56102930; called by muse, mutect2, varscan2
- GDAP1 | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.006); catalogued as COSV55184756; called by muse, mutect2, varscan2
- GEN1 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58055035; called by muse, mutect2, varscan2
- GMEB1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs960217167, COSV53792646; called by muse, mutect2, varscan2
- GNB1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as COSV66099646; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNPAT | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64152908; called by muse, mutect2
- GNS | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767876998, COSV50693885; called by muse, mutect2, varscan2
- GPAM | c.1038del p.D346Efs*3 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | catalogued as COSV62080081; called by mutect2, pindel, varscan2
- GPR157 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101072568; called by mutect2, varscan2
- GPT | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416735347, COSV52952060; called by muse, mutect2, varscan2
- GRIK3 | c.671G>A p.G224D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs1023191275, COSV66134840; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 4/8 reads (50%) | catalogued as rs754199513; called by mutect2, varscan2
- GSK3A | c.998T>C p.I333T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99725170; called by muse, mutect2, varscan2
- GSPT1 | c.727C>T p.P243S (on ENST00000420576 / NM_001130007.2; = p.P381S on NM_002094.4) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV70452358; called by muse, mutect2
- H1-3 | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV55096628; called by muse, mutect2, varscan2
- H1-8 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs149670868; called by muse, mutect2, varscan2
- H3C2 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); catalogued as COSV52518577; called by muse, mutect2, varscan2
- HABP4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs1420051493, COSV64514560; called by muse, mutect2
- HDAC9 | c.2218A>G p.T740A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67765491; called by muse, mutect2, varscan2
- HDLBP | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.273); catalogued as COSV60491559; called by muse, mutect2
- HEATR6 | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs756583158, COSV51743405; called by muse, mutect2, varscan2
- HERC2 | c.8000G>A p.G2667E | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55305121; called by muse, mutect2, varscan2
- HEYL | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs747977443, COSV65721306; called by mutect2, varscan2
- HFE | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.803); catalogued as rs28934889, CM994469; ClinVar: benign; called by muse, mutect2, varscan2
- HHIP | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs146905204; called by muse, mutect2, varscan2
- HID1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.529); catalogued as rs777264298, COSV59350919; called by mutect2, varscan2
- HMGXB3 | c.2914G>A p.V972M (on ENST00000613459; = p.V726M on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs753841260, COSV72211447; called by muse, mutect2, varscan2
- HNRNPA0 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100152888; called by muse, mutect2
- HOXB13 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748782183; ClinVar: uncertain significance; called by muse, varscan2
- HRAS | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as rs1473091760, COSV99529808; called by muse, mutect2, varscan2
- HRH1 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs138501310, COSV67954997; called by muse, mutect2, varscan2
- HSCB | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV53261835; called by muse, mutect2, varscan2
- HSD17B14 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs760796044, COSV54414915; called by muse, varscan2
- IFT74 | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV66285691; called by muse, mutect2, varscan2
- IGKV1-5 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs539543138; called by mutect2, varscan2
- IL17RA | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.536); catalogued as rs151220068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL18R1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs758012132, COSV52126847; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- IMMP2L | c.156del p.S53Afs*9 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs764675061; called by pindel, varscan2
- INPP5D | c.1963G>A p.A655T (on ENST00000445964 / NM_001017915.3; = p.A654T on NM_005541.5) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as rs756001826, COSV64035173; called by muse, mutect2, varscan2
- INPP5F | c.1050T>C p.S350= | Splice Region (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100740059; called by muse, mutect2, varscan2
- IQCC | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs748442077, COSV52207185; called by muse, mutect2, varscan2
- IQGAP3 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs749747273, COSV63248859, COSV63251190; called by muse, mutect2, varscan2
- ITGAM | c.1964G>A p.C655Y (on ENST00000648685 / NM_001145808.2; = p.C654Y on NM_000632.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54933088; called by muse, mutect2, varscan2
- ITPA | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs142979373; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR1 | c.2782G>A p.V928M (on ENST00000354582; = p.V913M on NM_002222.7) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs751172849, COSV56966167; called by muse, mutect2, varscan2
- JAKMIP2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54596644; called by muse, mutect2, varscan2
- JAZF1 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1236026612, COSV52231909; called by muse, mutect2, varscan2
- JMJD1C | c.3134A>T p.E1045V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV59514430; called by muse, mutect2, varscan2
- KALRN | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); catalogued as rs1293775314, COSV53760487; called by muse, mutect2, varscan2
- KANSL1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1258391982, COSV52264523; called by muse, mutect2, varscan2
- KCNA1 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748830362, COSV66836386; called by mutect2, varscan2
- KCNH1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV99658323; called by muse, mutect2, varscan2
- KCNJ8 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.991); catalogued as COSV53715616; called by muse, mutect2, varscan2
- KCNN3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769288919, COSV55211748; called by muse, mutect2, varscan2
- KDM2A | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV58188301; called by muse, mutect2, varscan2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs782541016; called by pindel, varscan2
- KDM4B | c.1832G>A p.R611Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV50208384; called by muse, mutect2, varscan2
- KDM8 | c.844-1G>T p.X282_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV53728142; called by muse, mutect2, varscan2
- KIAA1549L | c.2575C>T p.R859W (on ENST00000321505; = p.R1156W on NM_012194.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1247934271, COSV55768925; called by muse, mutect2, varscan2
- KIF5B | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377656602; called by muse, mutect2, varscan2
- KLHDC2 | c.739T>A p.Y247N | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53586410; called by muse, mutect2, varscan2
- KLHDC4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.892); catalogued as COSV54505713; called by muse, mutect2, varscan2
- KLHL4 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as rs1325990722, COSV64138597; called by muse, mutect2, varscan2
- KMT2C | c.6416G>A p.R2139Q | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1400133609, COSV51274419; called by muse, mutect2, varscan2
- KMT2D | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1420455563; called by muse, mutect2
- KRT37 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs375440985; called by muse, mutect2, varscan2
- KRT79 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs775879705, COSV57938097, COSV57938701; called by muse, mutect2, varscan2
- KRT81 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs542019661, COSV59811594; called by mutect2, varscan2
- KRT86 | c.1076C>T p.A359V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs534973333, COSV53291260; called by muse, mutect2, varscan2
- LAMA2 | c.5284C>T p.R1762W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs746492572, COSV70342198; called by mutect2, varscan2
- LAMA3 | c.6508C>T p.R2170C (on ENST00000313654 / NM_198129.4; = p.R561C on NM_000227.6) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753050180; called by muse, mutect2, varscan2
- LCP1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs755322384, COSV59940540; called by muse, varscan2
- LGALS4 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs761654023, COSV100313146; called by mutect2, varscan2
- LGR6 | c.1232G>A p.R411Q (on ENST00000367278 / NM_001017403.1; = p.R359Q on NM_021636.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs148689184; called by muse, mutect2, varscan2
- LIFR | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV54683634; called by muse, mutect2, varscan2
- LIG3 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747853708, COSV52009184; called by muse, mutect2, varscan2
- LILRB3 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV54427518; called by muse, mutect2, varscan2
- LIMK2 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749049788, COSV59181164; called by muse, mutect2, varscan2
- LINGO2 | c.1571C>G p.T524S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV58056327; called by muse, mutect2, varscan2
- LINGO2 | c.1033A>G p.R345G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58056340; called by mutect2, varscan2
- LMO7 | c.2522G>A p.R841H (on ENST00000357063; = p.R522H on NM_005358.5) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs760259550, COSV58528993; called by muse, mutect2, varscan2
- LPA | c.3280C>T p.P1094S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60295488; called by muse, mutect2, varscan2
- LRFN2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.782); catalogued as rs927930061, COSV57823149; called by muse, mutect2, varscan2
- LRP1B | c.7790G>A p.R2597H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs968042014, COSV67204592; called by muse, mutect2, varscan2
- LRP4 | c.3212A>T p.D1071V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66133717; called by muse, mutect2, varscan2
- LRRC15 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs111979102, COSV61649338; called by muse, mutect2, varscan2
- LRRC31 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99246535; called by muse, mutect2, varscan2
- LRRC42 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); catalogued as rs376545473; called by muse, mutect2, varscan2
- LRRC52 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1358439031, COSV99673764; called by muse, mutect2
- LRRC66 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs747783801, COSV100602878; called by muse, mutect2, varscan2
- LRRIQ4 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.184); catalogued as rs773032641, COSV61618550; called by muse, mutect2, varscan2
- MADD | c.3068A>G p.E1023G | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs768135729; called by muse, mutect2, varscan2
- MAN1B1 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100857323; called by muse, mutect2, varscan2
- MAN2C1 | c.3098T>C p.L1033P | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51226367; called by muse, mutect2, varscan2
- MANEAL | c.1059G>A p.M353I (on ENST00000373045 / NM_001113482.1; = p.M131I on NM_152496.2) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as rs1056938669, COSV100203882; called by muse, mutect2, varscan2
- MAP1B | c.287-1G>T p.X96_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV57093129, COSV57100178; called by muse, varscan2
- MAP4K4 | c.2689C>T p.R897W (on ENST00000347699 / NM_001242559.2; = p.R815W on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs781009612, COSV100153651, COSV56326004; called by muse, mutect2, varscan2
- MAP6 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774595883, COSV59075108; called by mutect2, varscan2
- MAPK13 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs762484290, COSV52982038; called by mutect2, varscan2
- MARCHF3 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs548204139, COSV58033885; called by muse, mutect2, varscan2
- MARCHF8 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs573798318, COSV60570420; called by muse, mutect2, varscan2
- MARK1 | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.158); catalogued as COSV100857138; called by muse, mutect2, varscan2
- MARK3 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53505620; called by muse, mutect2, varscan2
- MBD1 | c.1036C>T p.R346W (on ENST00000269468 / NM_001323950.1; = p.R323W on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568217739, COSV53997596; called by muse, varscan2
- MCHR2 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV55999018; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs773080349; called by mutect2, varscan2
- MED13 | c.5734G>A p.A1912T | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV67261660; called by muse, varscan2
- MED25 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57202615; called by muse, mutect2, varscan2
- MEGF8 | c.5258G>A p.R1753Q (on ENST00000251268 / NM_001271938.2; = p.R1686Q on NM_001410.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.012); catalogued as rs201626121, COSV52073629, COSV52093392; called by muse, varscan2
- MEI1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.127); catalogued as rs377078458; called by muse, mutect2, varscan2
- MEP1A | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376658556; called by muse, mutect2, varscan2
- MEST | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV56227384; called by muse, mutect2, varscan2
- METTL21C | c.520del p.E174Kfs*18 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as rs760847518; called by mutect2, pindel, varscan2
- METTL27 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99936394; called by muse, mutect2, varscan2
- METTL8 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64548725; called by muse, mutect2, varscan2
- MFSD9 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); catalogued as rs753679276, COSV51492502; called by muse, mutect2, varscan2
- MGA | c.848_850del p.N283del | In Frame Del (DEL) | VAF 8/54 reads (15%) | catalogued as rs755488942; called by pindel, varscan2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs538500709; called by mutect2, varscan2
- MIS18A | c.656T>G p.L219R | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51588414; called by muse, mutect2, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | catalogued as rs747811015; called by mutect2, pindel, varscan2
- MMP12 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200973192, COSV100404873; called by muse, mutect2, varscan2
- MMP24 | c.393C>T p.I131= | Splice Region (SNP) | VAF 11/55 reads (20%) | catalogued as rs780711150, COSV55768163; called by muse, mutect2, varscan2
- MNX1 | c.1061G>A p.S354N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV53317433; called by muse, mutect2, varscan2
- MOCOS | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373537157; called by muse, varscan2
- MPO | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99832487; called by muse, mutect2, varscan2
- MRGPRX1 | c.560del p.L187Yfs*13 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as rs1390190298; called by mutect2, pindel, varscan2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MRM3 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58679106; called by muse, mutect2, varscan2
- MRPL11 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV60598253; called by muse, mutect2, varscan2
- MRPL28 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs772941032, COSV51737486; called by muse, mutect2, varscan2
- MRPS30 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV50181462; called by muse, mutect2, varscan2
- MRPS9 | c.490-1G>T p.X164_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as COSV51517779; called by muse, mutect2
- MS4A6A | c.553_554del p.T185Sfs*29 | Frame Shift Del (DEL) | VAF 4/21 reads (19%) | catalogued as COSV60616210; called by mutect2, pindel, varscan2
- MST1R | c.2264del p.G755Vfs*19 | Frame Shift Del (DEL) | VAF 5/32 reads (16%) | catalogued as rs1407832113; called by mutect2, pindel
- MTFR2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs781170588, COSV63078524; called by muse, mutect2, varscan2
- MTHFD1L | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781662230, COSV100944836; called by muse, mutect2, varscan2
- MTHFD2L | c.1033del p.I345Sfs*48 (on ENST00000395759 / NM_001144978.2; = p.I287Sfs*48 on NM_001004346.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/96 reads (15%) | catalogued as rs761538540; called by mutect2, pindel, varscan2
- MTMR1 | c.1393G>T p.G465* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV64892152, COSV64892732; called by muse, mutect2, varscan2
- MTUS2 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs780725343, COSV54982837; called by muse, mutect2, varscan2
- MUC16 | c.19660G>A p.D6554N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.728); catalogued as COSV67440750; called by muse, mutect2, varscan2
- MUC17 | c.7603C>T p.L2535F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.86); catalogued as rs374380111, COSV60278964; called by muse, mutect2, varscan2
- MUCL3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs374902569; called by muse, mutect2, varscan2
- MUSK | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV51877094; called by muse, varscan2
- MUTYH | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs587782165, COSV58343385; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYCL | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV65692970; called by muse, mutect2, varscan2
- MYCN | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs144939456, COSV55258707; called by mutect2, varscan2
- MYH9 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs760489771, COSV99338405; called by muse, mutect2, varscan2
- MYO10 | c.4408G>A p.G1470R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1329844312, COSV57016053; called by muse, mutect2, varscan2
- MYO15A | c.8651C>T p.A2884V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs199864860, COSV52750989; called by muse, mutect2, varscan2
- MYO3B | c.3670C>T p.R1224W | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs778515727, COSV58692498; called by muse, mutect2, varscan2
- MYO5C | c.1448C>T p.T483M | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762003225, COSV55902092; called by muse, mutect2, varscan2
- MYOCD | c.1440del p.S481Pfs*18 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV58513333; called by mutect2, pindel, varscan2
- NAF1 | c.1322del p.P441Hfs*7 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV56806106; called by mutect2, pindel, varscan2
- NAMPT | c.777del p.D260Mfs*7 | Frame Shift Del (DEL) | VAF 26/142 reads (18%) | catalogued as COSV55994103; called by mutect2, pindel, varscan2
- NAV2 | c.2891T>C p.L964P (on ENST00000396087 / NM_001244963.2; = p.L941P on NM_145117.5) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60656036, COSV60657451; called by muse, mutect2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs763376147; called by mutect2, varscan2
- NCAM1 | c.1522G>T p.D508Y (on ENST00000316851 / NM_181351.5; = p.D498Y on NM_000615.7) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57509475; called by muse, mutect2, varscan2
- NCOA2 | c.572C>A p.P191Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.973); catalogued as COSV99069493; called by muse, mutect2, varscan2
- NCOA6 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs751187935, COSV62860928; called by muse, mutect2, varscan2
- NCOR1 | c.6278T>C p.V2093A | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV51958842; called by muse, mutect2, varscan2
- NCOR1 | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV51958868; called by muse, mutect2, varscan2
- NDST2 | c.2543C>T p.T848M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs140537578, COSV55212485; called by muse, mutect2, varscan2
- NDUFB3 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.598); catalogued as COSV52987357; called by muse, mutect2, varscan2
- NDUFS2 | c.96-2A>G p.X32_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100917400; called by muse, mutect2, varscan2
- NEK4 | c.2519A>T p.N840I | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99236810; called by muse, mutect2, varscan2
- NEMP1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs767023948, COSV55661443; called by muse, mutect2, varscan2
- NID2 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149213118; called by mutect2, varscan2
- NOL4 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs748692663, COSV52336534, COSV99308319; called by muse, varscan2
- NOLC1 | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as COSV53388315, COSV99531493; called by muse, mutect2
- NOVA1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV57471382; called by muse, mutect2, varscan2
- NR3C1 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.239); catalogued as rs750359967, COSV51539506; called by muse, mutect2, varscan2
- NR3C2 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60984600, COSV61000554; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs776154715; called by mutect2, varscan2
- NUP62CL | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763774979, COSV65236041, COSV65236110; called by muse, mutect2
- NUTM2F | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762405937, COSV53555038; called by muse, mutect2, varscan2
- OBSCN | c.13283G>A p.R4428Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs761455138, COSV99475607; called by muse, varscan2
- ODF2 | c.2116C>T p.R706W (on ENST00000434106 / NM_153433.2; = p.R682W on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs150531089; called by muse, mutect2, varscan2
- ODF2L | c.1221del p.K407Nfs*22 (on ENST00000317336; = p.K378Nfs*22 on NM_020729.3) | Frame Shift Del (DEL) | VAF 13/117 reads (11%) | catalogued as rs761049141, COSV54018443; called by mutect2, varscan2
- OPN1SW | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769004186, COSV50821148; called by muse, mutect2, varscan2
- OR2B2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs371031773; called by muse, mutect2, varscan2
- OR2M5 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV100822788; called by muse, mutect2, varscan2
- OR2T27 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs757391223, COSV100788324, COSV61281501, COSV61283032; called by mutect2, varscan2
- OR4K5 | c.535del p.C179Vfs*20 | Frame Shift Del (DEL) | VAF 15/137 reads (11%) | catalogued as rs1566497842; called by mutect2, pindel, varscan2
- OR52E4 | c.293del p.G98Dfs*39 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as COSV57623939; called by mutect2, varscan2
- OR6B3 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs757786017, COSV60113560; called by muse, varscan2
- OSGIN2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs780270897, COSV52406840; called by muse, mutect2, varscan2
- OSMR | c.2254G>A p.V752I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs145073771; called by muse, mutect2, varscan2
- OTOP2 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as rs753469262, COSV58880359; called by muse, mutect2, varscan2
- OVCH1 | c.1370T>C p.I457T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs781727670, COSV58958930; called by muse, mutect2, varscan2
- OXCT2 | c.1414G>A p.V472M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs755094827, COSV100560260, COSV59593097; called by muse, mutect2, varscan2
- OXSR1 | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61260640; called by muse, varscan2
- P2RX3 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.636); catalogued as rs1241532267, COSV54441285; called by muse, mutect2, varscan2
- P3H1 | c.1909G>A p.V637M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs983158177, COSV52531255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PABPC4L | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs373992035, COSV69930491; called by muse, mutect2, varscan2
- PADI4 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs767499070, COSV64922903; called by muse, mutect2, varscan2
- PAK2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59078947; called by muse, mutect2, varscan2
- PAM | c.1298del p.K433Rfs*32 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs1235994663; called by mutect2, varscan2
- PARVA | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.34); catalogued as rs559971958, COSV100616535; called by muse, mutect2, varscan2
- PBX2 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); catalogued as rs982109696, COSV66709251; called by muse, mutect2, varscan2
- PCDHA8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.214); catalogued as COSV65334962; called by muse, mutect2, varscan2
- PCDHGA7 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99534628; called by muse, mutect2, varscan2
- PCDHGB6 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as rs948480349, COSV53891778, COSV99539636; called by muse, mutect2, varscan2
- PCGF3 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1206319800, COSV62858126; called by muse, mutect2, varscan2
- PCNX1 | c.5419G>A p.A1807T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53088345; called by muse, mutect2, varscan2
- PDE4B | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs769931436, COSV58464273; called by muse, mutect2, varscan2
- PDE4DIP | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs782310936, COSV57671479; called by muse, mutect2, varscan2
- PDE6A | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs199925117, CM1312872; called by muse, mutect2, varscan2
- PDGFRB | c.2384C>A p.S795Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55810926; called by muse, mutect2, varscan2
- PDLIM2 | c.916C>T p.R306C (on ENST00000397760; = p.R556C on NM_021630.6) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762318482, COSV56131460; called by muse, mutect2, varscan2
- PDZD11 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52103088; called by muse, mutect2, varscan2
- PFKP | c.2195T>C p.V732A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV56525086; called by muse, mutect2, varscan2
- PGBD4 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56626302; called by muse, mutect2, varscan2
- PGBD5 | c.474del p.H158Qfs*33 (on ENST00000525115; = p.H227Qfs*33 on NM_001258311.2) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as COSV58410306, COSV58410659; called by mutect2, pindel, varscan2
- PGR | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV54795267; called by muse, mutect2, varscan2
- PGRMC1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs1294477913, COSV54291792; called by muse, mutect2, varscan2
- PHF11 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs767620664, COSV62896109; called by muse, mutect2, varscan2
- PHF12 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs746254087, COSV52017804; called by muse, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF3 | c.2910dup p.R971Sfs*6 | Frame Shift Ins (INS) | VAF 32/229 reads (14%) | catalogued as rs755026826; called by mutect2, varscan2
- PHF8 | c.1774G>T p.D592Y (on ENST00000357988 / NM_001184896.1; = p.D556Y on NM_015107.3) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57676724; called by muse, mutect2, varscan2
- PIK3R1 | c.1344del p.K448Nfs*32 (on ENST00000521381 / NM_181523.3; = p.K178Nfs*32 on NM_181504.4) | Frame Shift Del (DEL) | VAF 23/181 reads (13%) | catalogued as rs1289537429; called by mutect2, pindel, varscan2
- PIK3R1 | c.1694G>A p.S565N (on ENST00000521381 / NM_181523.3; = p.S295N on NM_181504.4) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV57122739, COSV57133761; called by muse, mutect2, varscan2
- PIWIL1 | c.2002G>T p.G668* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV99806200; called by muse, mutect2
- PIWIL4 | c.2441C>T p.P814L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs200034919, COSV54406860; called by muse, mutect2, varscan2
- PKD1L2 | c.2179C>A p.L727I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV55157494; called by muse, mutect2, varscan2
- PKD2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs755031837, COSV52936165, COSV52941771; called by muse, mutect2, varscan2
- PKD2L1 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as rs770922461, COSV58394340; called by muse, mutect2, varscan2
- PKDREJ | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772834468, COSV53546087, COSV99479687; called by muse, mutect2, varscan2
- PKHD1L1 | c.8310G>A p.W2770* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV65735939; called by muse, mutect2, varscan2
- PLAAT1 | c.725A>G p.N242S (on ENST00000650797; = p.N137S on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs746226759; called by muse, mutect2, varscan2
- PLD1 | c.2593C>T p.L865F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.046); catalogued as rs749248057, COSV60564893; called by muse, mutect2, varscan2
- PLEKHM1 | c.1816C>T p.R606C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760295037, COSV69598463; called by muse, mutect2, varscan2
- PLEKHM2 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV101009079; called by muse, mutect2, varscan2
- PLG | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99804497; called by muse, mutect2, varscan2
- PLK1 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55620171; called by muse, mutect2, varscan2
- PLK1 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1379177197, COSV55622956; called by muse, mutect2
- PMS1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as COSV59714391; called by muse, mutect2, varscan2
- PNLDC1 | c.478T>A p.W160R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51703459; called by muse, mutect2, varscan2
- PNMA1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1415642594, COSV54092207; called by muse, mutect2, varscan2
- PNMA1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV54098116; called by muse, mutect2, varscan2
- PNPLA7 | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1026559922, COSV52993261; called by muse, mutect2, varscan2
- POFUT2 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as rs748785565, COSV57957513; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs745933237; called by pindel, varscan2
- POLQ | c.4151C>T p.A1384V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749686819, COSV51744902; called by muse, mutect2, varscan2
- POLR1B | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV99637450; called by muse, mutect2, varscan2
- POTEE | c.2077G>A p.A693T | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1423103556; called by muse, mutect2
- PPM1B | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs758211363, COSV99175734; called by muse, mutect2, varscan2
- PPP2CA | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV51538467; called by muse, mutect2, varscan2
- PPP5C | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs778377016; called by mutect2, varscan2
- PPP6R3 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs143925321; called by muse, mutect2, varscan2
- PRAG1 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as rs373963411, COSV100422147; called by muse, mutect2, varscan2
- PRDM2 | c.4768A>G p.K1590E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as rs1166590013, COSV52454422; called by muse, mutect2, varscan2
- PRDM4 | c.2073G>C p.Q691H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57304443; called by muse, mutect2, varscan2
- PRKCB | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV57763793; called by muse, mutect2
- PRODH2 | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV56558003; called by muse, mutect2, varscan2
- PRPF19 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs770302443, COSV57126868; called by muse, mutect2
- PRPF8 | c.4850G>A p.R1617Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1242961736, COSV100517137; called by muse, mutect2, varscan2
- PRPS1 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV65054127; called by muse, mutect2, varscan2
- PRRC2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1212621247, COSV61933496; called by muse, mutect2, varscan2
- PRSS58 | c.680T>A p.I227N | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73488417; called by mutect2, varscan2
- PSCA | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs782393686, COSV56652241; called by muse, varscan2
- PTK2B | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.013); catalogued as rs188634353, COSV57748976; called by mutect2, varscan2
- PTPN12 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1051317645, COSV50353988; called by muse, varscan2
- PTPN14 | c.3061C>T p.R1021* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as rs771183448, COSV65281053; called by muse, mutect2, varscan2
- PTPRN | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs140457149; called by muse, mutect2, varscan2
- PTPRN2 | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs146255697, COSV67061205; called by muse, mutect2
- PUS10 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775384759; called by mutect2, varscan2
- PXMP2 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765325030, COSV58094617; called by muse, mutect2, varscan2
- QRICH2 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs138608770, COSV53150260, COSV53156432; called by muse, mutect2, varscan2
- RAD54L2 | c.1744C>T p.R582W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559647350, COSV56576751; called by muse, mutect2, varscan2
- RALGAPA1 | c.5126A>G p.Q1709R | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV99354064; called by muse, mutect2, varscan2
- RALGAPB | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99484967; called by muse, mutect2, varscan2
- RAP1A | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV62725911; called by muse, mutect2
- RASAL1 | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55653487; called by mutect2, varscan2
- RB1CC1 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs746797101, COSV50242890; called by muse, mutect2, varscan2
- RBFA | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs750196990, COSV51532535; called by muse, mutect2, varscan2
- RBM44 | c.112dup p.I38Nfs*44 (on ENST00000611254; = p.I672Nfs*44 on NM_001080504.2) | Frame Shift Ins (INS) | VAF 12/95 reads (13%) | catalogued as rs777249522; called by mutect2, pindel, varscan2
- RCBTB2 | c.673del p.E225Rfs*46 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as COSV60652136; called by mutect2, pindel, varscan2
- REL | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99691948; called by muse, varscan2
- REPS1 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs371133360; called by muse, mutect2, varscan2
- REV3L | c.6718G>A p.D2240N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100725362; called by muse, mutect2, varscan2
- RFX4 | c.2120C>T p.T707M (on ENST00000392842 / NM_213594.3; = p.T613M on NM_032491.6) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.454); catalogued as rs202235460; called by muse, mutect2, varscan2
- RGL3 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1011746987, COSV62696993; called by muse, mutect2
- RIF1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54611726; called by muse, mutect2, varscan2
- RNF139 | c.1676del p.R559Lfs*60 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | catalogued as COSV52677298; called by mutect2, pindel, varscan2
- RNF40 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61213260; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs755128667, COSV68457540; called by pindel, varscan2
- ROBO1 | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV71391367; called by muse, mutect2, varscan2
- ROCK2 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV55075306; called by muse, mutect2, varscan2
- RP2 | c.852del p.A285Hfs*8 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as CP015812; called by mutect2, pindel, varscan2
- RPH3A | c.985C>T p.R329* (on ENST00000389385 / NM_001143854.2; = p.R325* on NM_014954.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as rs746728163, COSV66989863; called by muse, mutect2, varscan2
- RPS7 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV100513958; called by muse, mutect2
- RPTOR | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs745951041, COSV60806410, COSV60812724; called by mutect2, varscan2
- RRAGB | c.1019C>T p.P340L (on ENST00000262850 / NM_016656.4; = p.P312L on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV53328281; called by muse, mutect2, varscan2
- RSPH10B | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370666026; called by muse, mutect2, varscan2
- S1PR1 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100541724; called by muse, mutect2, varscan2
- SAFB2 | c.2471del p.G824Afs*8 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs759920279; called by mutect2, pindel, varscan2
- SAMD9 | c.3067G>T p.G1023* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV66072684; called by muse, mutect2, varscan2
- SAMHD1 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1371480402, COSV53428034; called by muse, mutect2, varscan2
- SATB2 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as COSV53477171; called by muse, mutect2, varscan2
- SATL1 | c.1069C>T p.R357* (on ENST00000395409; = p.R544* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as COSV60576027, COSV60576401; called by muse, mutect2, varscan2
- SAXO2 | c.817del p.R273Efs*13 | Frame Shift Del (DEL) | VAF 18/92 reads (20%) | catalogued as rs1567095900; called by mutect2, pindel, varscan2
- SBF2 | c.1276T>A p.S426T | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56290001; called by muse, mutect2, varscan2
- SBNO1 | c.1276G>A p.G426S (on ENST00000420886; = p.G425S on NM_018183.5) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs150793785; called by muse, mutect2, varscan2
- SCNN1B | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV56301043; called by muse, mutect2, varscan2
- SEC16A | c.3110T>C p.L1037P | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51520885; called by muse, mutect2
- SEC23A | c.1140del p.L381Yfs*26 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1381673861; called by mutect2, pindel, varscan2
- SEMA3A | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs143007146, CM130574; called by muse, mutect2, varscan2
- SEMA4D | c.1157T>C p.L386S | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59390431; called by muse, mutect2, varscan2
- SEMA6B | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769299847, COSV56701879; called by muse, mutect2, varscan2
- SEPTIN5 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63530312; called by muse, varscan2
- SERPINA3 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as rs770816070; called by mutect2, varscan2
- SETD1A | c.3381del p.S1128Vfs*134 | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | catalogued as rs1373270249; called by mutect2, varscan2
- SFXN3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99827425; called by muse, mutect2, varscan2
- SGPP2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990071082, COSV58326914; called by muse, mutect2, varscan2
- SHANK2 | c.3833C>T p.T1278M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs782409092, COSV53583639; called by muse, mutect2, varscan2
- SIGLEC11 | c.1339G>A p.V447I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs749024800, COSV70221862; called by muse, mutect2, varscan2
- SIN3A | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1350898288, COSV100845094; called by muse, mutect2, varscan2
- SIPA1L1 | c.4514G>A p.R1505H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs370837924; called by muse, mutect2, varscan2
- SKAP1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs142272724; called by mutect2, varscan2
- SKIV2L | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.182); catalogued as rs1174989838, COSV64810018; called by muse, mutect2, varscan2
- SLC16A14 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140668369; called by muse, mutect2, varscan2
- SLC1A7 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65201689; called by muse, mutect2, varscan2
- SLC22A9 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs756160377, COSV54166826; called by muse, mutect2, varscan2
- SLC25A46 | c.1052A>T p.D351V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63506372; called by muse, mutect2, varscan2
- SLC26A6 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs765049864, COSV50839459; called by muse, varscan2
- SLC26A8 | c.2440G>A p.V814M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV100839416; called by muse, mutect2, varscan2
- SLC30A7 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.216); catalogued as COSV63016613; called by muse, mutect2, varscan2
- SLC35B1 | c.905G>A p.G302D (on ENST00000649906; = p.G265D on NM_005827.4) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53601934; called by muse, mutect2, varscan2
- SLC35E4 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as rs764799861; called by muse, mutect2
- SLC38A6 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746907758, COSV50780880; called by muse, mutect2, varscan2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 34/228 reads (15%) | catalogued as rs771462597; called by mutect2, varscan2
- SLC39A11 | c.757C>T p.R253* (on ENST00000542342 / NM_001159770.2; = p.R246* on NM_139177.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as rs142390666; called by mutect2, varscan2
- SLC39A12 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140968814, COSV66194432; called by mutect2, varscan2
- SLC44A2 | c.1939G>A p.V647I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs148958474; called by muse, mutect2, varscan2
- SLC46A3 | c.926del p.L309* | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as COSV99906530; called by mutect2, pindel, varscan2
- SLC4A2 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs749356650, COSV59655481; called by muse, mutect2, varscan2
- SLC4A7 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560270432, COSV55394298; called by muse, mutect2, varscan2
- SLC7A8 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145886415; called by muse, mutect2, varscan2
- SLC8A2 | c.658del p.S220Pfs*12 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs748349403; called by mutect2, pindel, varscan2
- SLCO6A1 | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1439999258, COSV65805218; called by muse, mutect2, varscan2
- SLIT3 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100266388; called by muse, mutect2, varscan2
- SLITRK3 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV99578852; called by muse, mutect2, varscan2
- SMC2 | c.3488A>G p.D1163G | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99658754; called by muse, varscan2
- SMC4 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs779745638, COSV61002668; called by muse, mutect2, varscan2
- SMG1 | c.3839C>T p.P1280L | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs766665415, COSV67173774; called by muse, varscan2
- SMG1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs762928481, COSV67169149; called by muse, mutect2, varscan2
- SMG9 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV54213304; called by muse, mutect2, varscan2
- SMOX | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs370133256; called by mutect2, varscan2
- SMYD1 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.205); catalogued as COSV70224314; called by muse, mutect2, varscan2
- SNCAIP | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1231223761; called by muse, mutect2, varscan2
- SNRNP70 | c.46dup p.R16Pfs*2 | Frame Shift Ins (INS) | VAF 8/49 reads (16%) | catalogued as rs1183371144; called by mutect2, pindel, varscan2
- SNTG1 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs144283676, COSV52466221; called by muse, mutect2, varscan2
- SNX2 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65347529; called by muse, mutect2, varscan2
- SOCS3 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58269680, COSV58271053; called by muse, mutect2, varscan2
- SOWAHD | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV59649383; called by muse, mutect2
- SOX13 | c.701del p.P234Qfs*41 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as COSV65826761; called by mutect2, pindel, varscan2
- SOX6 | c.1834C>T p.R612C (on ENST00000528429 / NM_001145819.2; = p.R585C on NM_017508.3) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434670578, COSV57035391; called by muse, mutect2, varscan2
- SPATC1 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs782061691, COSV66297990; called by muse, mutect2
- SPATS1 | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs1387921113, COSV55821783; called by muse, mutect2, varscan2
- SPEG | c.7651C>T p.R2551W | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV100403937; called by muse, mutect2, varscan2
- SPEM2 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748868476, COSV61602992; called by muse, mutect2, varscan2
- SPG11 | c.5651G>A p.R1884H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs767776590, COSV55990184; called by mutect2, varscan2
- SPTAN1 | c.5405T>C p.L1802P | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100823405; called by muse, mutect2, varscan2
- SRBD1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs915522930, COSV55407794; called by muse, mutect2, varscan2
- SSB | c.1048T>C p.S350P | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV53625730; called by muse, mutect2, varscan2
- STARD8 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV52921152, COSV52931192; called by muse, mutect2, varscan2
- STC2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs925905197, COSV54177982; called by muse, mutect2, varscan2
- STIL | c.1699C>A p.P567T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.045); catalogued as COSV99680781; called by muse, mutect2, varscan2
- STK11IP | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as rs766908488, COSV55245254; called by mutect2, varscan2
- STK25 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342567968, COSV50868794; called by muse, mutect2, varscan2
- STON1 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150634127; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3169G>A p.G1057S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1203946672, COSV59131247; called by muse, mutect2, varscan2
- SULF1 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs754990510, COSV52694717, COSV99482007; called by muse, mutect2, varscan2
- SUMF2 | c.592+1G>A p.X198_splice (on ENST00000652303; = p.X179_splice on NM_015411.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99305019; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs770033147; called by mutect2, pindel, varscan2
- SYBU | c.629G>T p.R210M (on ENST00000276646 / NM_001099754.2; = p.R209M on NM_017786.6) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52613689; called by muse, mutect2, varscan2
- SYNE2 | c.14260G>T p.G4754W | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59938212; called by muse, mutect2, varscan2
- TAAR6 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs770532856, COSV51584340; called by muse, mutect2, varscan2
- TAF15 | c.535G>A p.G179R (on ENST00000605844 / NM_139215.3; = p.G176R on NM_003487.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs780771102; called by muse, mutect2, varscan2
- TANC2 | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.024); catalogued as rs765187847, COSV67329251, COSV67331753; called by mutect2, varscan2
- TBATA | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 8/35 reads (23%) | catalogued as rs1273299385, COSV54717020; called by muse, mutect2, varscan2
- TBC1D4 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66487367; called by muse, mutect2, varscan2
- TBX21 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs757416045, COSV51594760; called by muse, mutect2
- TCEANC | c.441G>T p.K147N (on ENST00000380600 / NM_001297563.2; = p.K177N on NM_152634.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769744727, COSV59039117; called by muse, mutect2, varscan2
- TGFBR1 | c.700T>A p.F234I | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM064319; called by muse, mutect2
- THEM5 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs753923316, COSV64312656; called by muse, mutect2, varscan2
- TICRR | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs746440485, COSV51537264; called by muse, mutect2, varscan2
- TLK1 | c.581T>C p.L194S | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1197470214, COSV62628564; called by muse, varscan2
- TLN1 | c.3817C>T p.R1273* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs769049864, COSV100147541; called by muse, mutect2, varscan2
- TMC2 | c.728-2A>C p.X243_splice | Splice Site (SNP) | VAF 6/39 reads (15%) | catalogued as COSV62649309; called by muse, mutect2, varscan2
- TMCO6 | c.1027T>C p.F343L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.638); catalogued as COSV99347081; called by muse, mutect2, varscan2
- TMED8 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774060958, COSV53625064, COSV53626408; called by muse, mutect2, varscan2
- TMEM222 | c.611T>A p.V204D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV65026809; called by muse, mutect2
- TMEM241 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs778244273, COSV67242728; called by mutect2, varscan2
- TMEM244 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV63742475; called by muse, mutect2, varscan2
- TMEM44 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV56446960; called by muse, mutect2, varscan2
- TMEM63C | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs775465316, COSV53600763; called by mutect2, varscan2
- TMPO | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as COSV54121821; called by muse, mutect2, varscan2
- TMPRSS7 | c.922G>A p.D308N (on ENST00000452346; = p.D182N on NM_001042575.2) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs367735856; called by muse, mutect2, varscan2
- TMTC1 | c.1156G>A p.G386S (on ENST00000539277 / NM_001193451.2; = p.G278S on NM_175861.3) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs910785203, COSV55477210; called by muse, mutect2, varscan2
- TMX3 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 53/358 reads (15%) | catalogued as rs757393640, COSV55184479; called by muse, mutect2, varscan2
- TNFRSF19 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs149498209; called by muse, mutect2, varscan2
- TNRC6C | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs778201969, COSV56951956; called by muse, mutect2
- TNS1 | c.2741G>A p.R914H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.781); catalogued as rs186255060; called by muse, mutect2, varscan2
- TP53I13 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1490658624, COSV56401607; called by muse, varscan2
- TPD52L3 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV58827834, COSV58829025; called by muse, mutect2, varscan2
- TRAF5 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs113925874; called by mutect2, varscan2
- TRAPPC12 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368315810, COSV60849998; called by muse, mutect2, varscan2
- TRIB1 | c.1039A>G p.I347V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs776955393, COSV61334093; called by muse, mutect2, varscan2
- TRIM15 | c.605G>T p.R202M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV64988820; called by muse, mutect2, varscan2
- TRIM8 | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747235303, COSV56659039; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 19/128 reads (15%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPA1 | c.3237G>T p.E1079D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as COSV100083697; called by mutect2, varscan2
- TRPM8 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs200473098, COSV61220278, COSV61221621; called by mutect2, varscan2
- TRPM8 | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs765451235, COSV61221987; called by muse, mutect2, varscan2
- TRPV5 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs771239971, COSV54682696; called by muse, mutect2, varscan2
- TRRAP | c.4415G>A p.R1472H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV62837858; called by muse, mutect2, varscan2
- TTBK2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51157145; called by muse, mutect2, varscan2
- TTC23L | c.185G>A p.C62Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72205729; called by muse, mutect2, varscan2
- TTC37 | c.4620C>T p.D1540= | Splice Region (SNP) | VAF 9/47 reads (19%) | catalogued as rs781261383, COSV62453187; called by muse, mutect2, varscan2
- TTN | c.90635G>A p.R30212H (on ENST00000591111; = p.R22788H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | PolyPhen benign (0.015); catalogued as rs754151944, COSV59966937; called by muse, mutect2, varscan2
- TTN | c.83809C>T p.R27937C (on ENST00000591111; = p.R20513C on NM_003319.4) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | PolyPhen probably damaging (0.998); catalogued as rs539906386, COSV59861148; called by muse, mutect2, varscan2
- TTN | c.65501G>A p.R21834H (on ENST00000591111; = p.R14410H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | PolyPhen possibly damaging (0.869); catalogued as rs370257707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14881G>A p.A4961T (on ENST00000591111; = p.A4034T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | PolyPhen probably damaging (0.998); catalogued as rs754692422, COSV59861214, COSV60157889; called by muse, mutect2
- TUB | c.1204C>T p.R402C (on ENST00000299506 / NM_177972.3; = p.R457C on NM_003320.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as rs144484513, COSV55107327; called by mutect2, varscan2
- TUBD1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as rs774496103, COSV57871660; called by mutect2, varscan2
- TUT7 | c.2950A>G p.R984G | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99462702; called by muse, mutect2, varscan2
- UBA1 | c.2413G>A p.V805I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs868958168, COSV60110843, COSV60111082; called by muse, mutect2, varscan2
- UBE2W | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs775096274, COSV100708747; called by muse, mutect2, varscan2
- UBFD1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54840903; called by muse, mutect2, varscan2
- UGT2B7 | c.1310+1G>A p.X437_splice | Splice Site (SNP) | VAF 22/149 reads (15%) | catalogued as rs753618139, COSV59441759, COSV59445888; called by muse, mutect2, varscan2
- UGT8 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60421321; called by muse, mutect2, varscan2
- UHRF1 | c.389C>T p.T130M (on ENST00000612630 / NM_001290050.1; = p.T143M on NM_013282.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.535); catalogued as rs371706472; called by mutect2, varscan2
- UHRF2 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52790478; called by muse, mutect2, varscan2
- ULBP1 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as rs115012653, COSV57663388; called by muse, mutect2, varscan2
- UNK | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53138834; called by muse, mutect2, varscan2
- USP24 | c.2959C>T p.R987W | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772334656, COSV53760911; called by mutect2, varscan2
- USP26 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.411); catalogued as rs189158778, COSV63707932; called by muse, mutect2, varscan2
- UTY | c.3928C>T p.R1310* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as rs992601194; called by muse, mutect2, varscan2
- VAMP1 | c.59del p.G20Vfs*9 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1311863343, COSV56946582; called by mutect2, pindel, varscan2
- VCP | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62719463; called by muse, varscan2
- VDR | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV57466670; called by muse, mutect2
- VPS13C | c.7625G>A p.R2542H (on ENST00000644861 / NM_020821.3; = p.R2499H on NM_017684.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs146692144; called by muse, mutect2, varscan2
- VPS53 | c.388C>T p.R130C (on ENST00000571805 / NM_001366253.2; = p.R101C on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs759207499, COSV52125527; called by muse, mutect2, varscan2
- VTN | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs782315239, COSV52645698; called by muse, mutect2, varscan2
- VWA5B1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs574917690, COSV57061877, COSV99233147; called by mutect2, varscan2
- VWA8 | c.5506C>T p.R1836* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | catalogued as rs201130705, COSV64993577; called by muse, mutect2, varscan2
- WASHC2C | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV60489837; called by muse, mutect2, varscan2
- WASHC4 | c.2132del p.F711Sfs*3 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | catalogued as rs1236210910; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- WBP4 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV65273340; called by muse, mutect2, varscan2
- WDPCP | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV55419870; called by muse, mutect2
- WDR62 | c.1537A>C p.S513R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.548); catalogued as COSV99543441; called by muse, varscan2
- WDR87 | c.3695G>A p.R1232H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as rs760886366; called by muse, varscan2
- WLS | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52036591; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WRAP73 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as rs199984886, COSV54559803; called by muse, mutect2, varscan2
- WWP2 | c.2407C>T p.R803C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747018644, COSV100598506; called by muse, mutect2, varscan2
- XIRP2 | c.7909A>G p.R2637G (on ENST00000628543; = p.R2812G on NM_152381.6) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV54679623; called by muse, mutect2, varscan2
- YTHDF2 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs2318770, COSV65722475; called by muse, mutect2, varscan2
- ZC3H18 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.084); catalogued as rs200378104, COSV56322337; called by mutect2, varscan2
- ZFHX3 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.137); catalogued as rs764687875, COSV51706358; called by muse, mutect2, varscan2
- ZMYM2 | c.176A>T p.D59V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1317869278; called by muse, mutect2, varscan2
- ZNF155 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54205818; called by muse, mutect2, varscan2
- ZNF195 | c.1040A>G p.H347R (on ENST00000399602 / NM_001130520.3; = p.H275R on NM_007152.5) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456239502; called by muse, mutect2, varscan2
- ZNF256 | c.1733G>A p.S578N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56596016; called by muse, mutect2, varscan2
- ZNF510 | c.1458A>C p.K486N | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99793810; called by muse, mutect2, varscan2
- ZNF518A | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs374947264; called by muse, varscan2
- ZNF518B | c.1580T>C p.L527S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100456887, COSV58721099; called by muse, mutect2, varscan2
- ZNF521 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568023002, COSV64123636; called by muse, mutect2, varscan2
- ZNF608 | c.3074C>T p.T1025M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as rs200298566; called by muse, mutect2, varscan2
- ZNF676 | c.146A>G p.K49R (on ENST00000650058; = p.K17R on NM_001001411.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV68092014; called by muse, mutect2, varscan2
- ZNF727 | c.803G>A p.C268Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs774193383, COSV70701541; called by muse, mutect2, varscan2
- ACE | c.1369del p.M457Wfs*68 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- ACSS2 | c.394del p.E132Rfs*38 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- ADD3 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- AIFM1 | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
564 further variants in this file (188 protein-altering or splice-affecting, 282 silent, 94 other) are not listed here.
